Somatic mutation profile of tumor specimen 0DYKSH from CCDI case PBCSZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.9 years (5,817 days).
Specimen 0DYKSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c53df03-7e59-48dc-ac0a-4e2a61357453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYKRN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca4d642-3ea1-446c-972c-6d27f7391155

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NISCH | c.3797A>G p.H1266R | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- EIF5AL1 | c.*95T>C | 3'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs376353382; called by mutect2, varscan2
